TCGA case TCGA-EI-6508 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d8bfcc67-f5c3-42cd-9fc4-bd483f896da1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma in tubulovillous adenoma: ICD-O-3 morphology code: 8263/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 48.8 years (17,827 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 636 days (1.7 years).
   Pathology details: Circumferential resection margin: 12; Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 15; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Perineural invasion present: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 258 days; Number of cycles: 12; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 66 days; Disease response: Tumor Free.
- Days to follow up: 636 days (1.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 0.6 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 66 kg; Height: 159 cm; BMI: 26.1.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EI-6508-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-EI-6508-01A-01-TS1: Section location: Top; Percent tumor cells: 74; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 3; Percent stromal cells: 18.
  Slide TCGA-EI-6508-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-EI-6508-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EI-6508-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 0.6; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; Colon polyps at procurement indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: oxaliplatinum + 5-FU.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 636 days; disease-specific survival: no event (censored), 636 days; progression-free interval: no event (censored), 636 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EI-6508-01A-11D-1732-01): tumor purity 0.79, ploidy 1.95, whole-genome doublings 0.
